Somatic mutation profile of tumor specimen MMRF_2643_1_BM_CD138pos (aliquot MMRF_2643_1_BM_CD138pos_T1_KHS5U_L13413) from MMRF case MMRF_2643, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2643_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a29a3664-2192-4a45-a5bb-9214083d8ea1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2643_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2643_1_PB_WBC_C3_KHS5U_L13412; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70e8a021-d5e6-4d75-9f8d-fa056e46512d

The open-access MAF lists 191 somatic variants for this specimen: 87 protein-altering or splice-affecting, 23 silent, 81 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, 3'UTR 49, Silent 23, Intron 18, Nonsense Mutation 6, RNA 6, 5'UTR 4, Splice Site 3, 3'Flank 2, 5'Flank 2, Translation Start Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP6 | c.668A>T p.E223V | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57298886; called by mutect2, varscan2
- CDK12 | c.4066C>T p.R1356* (on ENST00000447079 / NM_016507.4; = p.R1347* on NM_015083.3) | Nonsense Mutation (SNP) | VAF 133/288 reads (46%) | catalogued as rs900412874, COSV101420297; called by muse, mutect2, varscan2
- CHRD | c.2176T>G p.C726G | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99200791; called by muse, mutect2, varscan2
- CORO1A | c.19C>A p.R7S | Missense Mutation (SNP) | VAF 132/246 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54630807; called by muse, mutect2, varscan2
- CRISPLD2 | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as rs569725982; called by muse, mutect2, varscan2
- CSMD1 | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68166585; called by muse, mutect2, varscan2
- EPS8L2 | c.779A>G p.N260S | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs940188070; called by muse, mutect2
- GNAT3 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 94/180 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775635099, COSV68069429; called by muse, mutect2, varscan2
- H2AC6 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100019863, COSV58417094; called by muse, mutect2, varscan2
- IGLV3-16 | c.160T>C p.Y54H | Missense Mutation (SNP) | VAF 84/153 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs762937196; called by muse, varscan2
- JAKMIP2 | c.743T>A p.L248H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54602624; called by muse, mutect2, varscan2
- KCNC4 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV63925860; called by muse, mutect2
- LRTM1 | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.192); catalogued as COSV99836096; called by muse, mutect2
- MEF2D | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1427310716; called by muse, mutect2, varscan2
- MPDZ | c.4592C>T p.A1531V | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV59921905; called by muse, mutect2
- NTNG1 | c.1553C>G p.P518R (on ENST00000370068 / NM_001113226.3; = p.P417R on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs372603693; called by muse, mutect2, varscan2
- NUP214 | c.5983G>A p.G1995S | Missense Mutation (SNP) | VAF 115/244 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs770633748; called by muse, varscan2
- PCDHGB5 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775633916; called by muse, mutect2, varscan2
- PLAG1 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs935625762; called by muse, mutect2, varscan2
- RUNDC3B | c.994C>A p.L332I | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV56692684; called by muse, mutect2, varscan2
- SCP2 | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 133/272 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV65262708; called by muse, mutect2, varscan2
- SNED1 | c.3629G>A p.G1210E | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1355918461, COSV60030686; called by muse, mutect2, varscan2
- TEP1 | c.6235G>A p.G2079R | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs201759110, COSV52999053; called by muse, mutect2, varscan2
- TMEM255B | c.591G>A p.W197* | Nonsense Mutation (SNP) | VAF 82/85 reads (96%) | catalogued as rs1301189712; called by muse, mutect2, varscan2
- TTLL8 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765915957, COSV56729823; called by muse, mutect2, varscan2
- ZNF726 | c.2097A>T p.K699N | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as rs1175157095, COSV58042183; called by muse, mutect2, varscan2
- ZSCAN1 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.054); catalogued as COSV56603728; called by muse, mutect2
- ADAM23 | c.2079-1G>T p.X693_splice | Splice Site (SNP) | VAF 26/129 reads (20%) | called by muse, mutect2, varscan2
- ARG2 | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- ARID1A | c.1758G>C p.Q586H | Missense Mutation (SNP) | VAF 111/222 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BICRAL | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 88/185 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- CA10 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2
- CLMN | c.2485G>C p.E829Q | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DNAH11 | c.8664G>C p.Q2888H | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); called by muse, mutect2
- DST | c.9292A>G p.T3098A | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2
- ESPNL | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FGA | c.1277G>T p.R426I | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); called by muse, mutect2
- FSCB | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GJA1 | c.214dup p.I72Nfs*48 | Frame Shift Ins (INS) | VAF 72/178 reads (40%) | called by mutect2, pindel, varscan2
- GPR149 | c.53A>T p.E18V | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- GTF3C1 | c.4252C>T p.L1418F | Missense Mutation (SNP) | VAF 10/320 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); called by muse, mutect2
- GYS2 | c.1138C>A p.L380M | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHV3-20 | c.43A>C p.K15Q | Missense Mutation (SNP) | VAF 136/140 reads (97%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IGLC2 | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 86/128 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- IGLV3-16 | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.073); called by muse, varscan2
- IKZF4 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF14 | c.3046C>A p.Q1016K | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2
- LAMA1 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LIPC | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- LTB | c.140T>A p.V47E | Missense Mutation (SNP) | VAF 99/203 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- MAP3K7 | c.437G>T p.S146I | Missense Mutation (SNP) | VAF 176/324 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- MT4 | c.172T>A p.C58S | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NCAM2 | c.2194C>A p.L732M | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- NOTCH4 | c.315C>A p.C105* | Nonsense Mutation (SNP) | VAF 68/137 reads (50%) | called by muse, mutect2, varscan2
- OLFM3 | c.653C>G p.T218R (on ENST00000338858 / NM_001288821.1; = p.T198R on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OR4B1 | c.603T>A p.S201R | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- PARD6G | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- PCDH15 | c.5577G>T p.K1859N | Missense Mutation (SNP) | VAF 117/242 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCTP | c.16G>T p.G6* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- PEX6 | c.1313T>G p.L438R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2
- PPFIBP1 | c.1278G>T p.K426N (on ENST00000318304 / NM_177444.3; = p.K409N on NM_003622.4) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRK | c.281A>C p.Q94P | Missense Mutation (SNP) | VAF 77/385 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- QSER1 | c.2188G>A p.A730T (on ENST00000399302; = p.A859T on NM_001076786.3) | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM20 | c.1405G>C p.V469L | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- REM1 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- RIF1 | c.6653A>C p.D2218A | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF227 | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 91/98 reads (93%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPL10L | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 85/170 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RXYLT1 | c.76C>G p.H26D | Missense Mutation (SNP) | VAF 134/634 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SALL4 | c.2839A>T p.K947* | Nonsense Mutation (SNP) | VAF 26/191 reads (14%) | called by muse, mutect2, varscan2
- SEC24A | c.817+2T>G p.X273_splice | Splice Site (SNP) | VAF 67/177 reads (38%) | called by muse, mutect2, varscan2
- SH3GL2 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 21/244 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.026); called by muse, mutect2
- SHANK1 | c.5852C>T p.P1951L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- SHANK1 | c.1830A>T p.E610D | Missense Mutation (SNP) | VAF 58/324 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SKOR2 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.167); called by muse, varscan2
- SLIT1 | c.3607C>A p.L1203I | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRRM4 | c.1738C>A p.R580S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- SS18 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SUPT6H | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SV2A | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TH | c.613G>C p.D205H (on ENST00000381178 / NM_199292.3; = p.D174H on NM_000360.4) | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TIE1 | c.3036G>T p.M1012I | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2
- TMEM132B | c.1434C>G p.N478K | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMF1 | c.2152-1G>A p.X718_splice | Splice Site (SNP) | VAF 81/175 reads (46%) | called by muse, mutect2, varscan2
- TTN | c.47924G>C p.W15975S (on ENST00000591111; = p.W8551S on NM_003319.4) | Missense Mutation (SNP) | VAF 63/311 reads (20%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDFY3 | c.74del p.L25Rfs*18 | Frame Shift Del (DEL) | VAF 89/176 reads (51%) | called by mutect2, varscan2
- ZNF536 | c.2080G>A p.V694I | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKRD12 | c.345T>C p.A115= | Silent (SNP) | VAF 42/184 reads (23%) | catalogued as rs1327071968; called by mutect2, varscan2
- ARHGAP10 | c.9G>A p.L3= | Silent (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- EFCAB1 | c.635G>A p.*212= | Silent (SNP) | VAF 39/223 reads (17%) | called by muse, mutect2, varscan2
- EPG5 | c.2202C>T p.N734= | Silent (SNP) | VAF 89/178 reads (50%) | called by muse, mutect2, varscan2
- FAM214B | c.1431C>T p.T477= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as rs775024483; called by muse, mutect2, varscan2
- FIGN | c.231C>T p.G77= | Silent (SNP) | VAF 63/145 reads (43%) | called by muse, mutect2, varscan2
- FNBP1 | c.555C>T p.D185= | Silent (SNP) | VAF 67/334 reads (20%) | catalogued as rs571486570; called by muse, mutect2, varscan2
- FRMD4B | c.1212T>C p.S404= | Silent (SNP) | VAF 23/272 reads (8%) | called by muse, mutect2
- GATA3 | c.117G>C p.A39= | Silent (SNP) | VAF 13/271 reads (5%) | called by muse, mutect2
- HMCN2 | c.10980C>T p.S3660= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs772168553; called by muse, mutect2, varscan2
- IGLV3-16 | c.66G>A p.E22= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as rs571416676; called by muse, varscan2
- IGLV3-16 | c.183C>T p.F61= | Silent (SNP) | VAF 58/144 reads (40%) | catalogued as rs1438752855; called by muse, varscan2
- MAP2 | c.3927G>A p.V1309= | Silent (SNP) | VAF 48/208 reads (23%) | called by muse, mutect2, varscan2
- NOP2 | c.1527A>G p.G509= (on ENST00000322166 / NM_001258308.2; = p.G505= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/206 reads (21%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1485G>C p.V495= | Silent (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- PDZRN3 | c.2214C>T p.H738= | Silent (SNP) | VAF 62/126 reads (49%) | called by muse, mutect2, varscan2
- SRCIN1 | c.2091C>T p.D697= (on ENST00000621492; = p.D663= on NM_025248.3) | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- ST6GAL2 | c.1497G>C p.T499= | Silent (SNP) | VAF 70/165 reads (42%) | catalogued as COSV62417769; called by muse, mutect2, varscan2
- SYNE1 | c.5928G>C p.L1976= (on ENST00000367255 / NM_182961.4; = p.L1983= on NM_033071.3) | Silent (SNP) | VAF 129/268 reads (48%) | called by muse, mutect2, varscan2
- TEX13C | c.2238C>A p.P746= | Silent (SNP) | VAF 95/114 reads (83%) | called by muse, mutect2, varscan2
- TLE6 | c.1689G>A p.E563= (on ENST00000246112 / NM_001143986.2; = p.E440= on NM_024760.3) | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs760158074; called by muse, mutect2, varscan2
- TLN1 | c.7338T>A p.A2446= | Silent (SNP) | VAF 90/178 reads (51%) | called by muse, mutect2, varscan2
- ZNF324B | c.1092G>A p.A364= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs769075987; called by muse, mutect2, varscan2
- ABL2 | c.*3591G>A | 3'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- ACSS3 | c.*4837T>C | 3'UTR (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- AGXT | c.*156C>A | 3'UTR (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- ANTXR2 | c.*5594T>G | 3'UTR (SNP) | VAF 51/102 reads (50%) | called by muse, mutect2, varscan2
- AP001347.1 | n.87T>A | RNA (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- APOC1P1 | n.47G>T | RNA (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2
- ARHGAP20 | c.*350C>T | 3'UTR (SNP) | VAF 9/171 reads (5%) | called by muse, mutect2
- ARL3 | c.*88T>C | 3'UTR (SNP) | VAF 194/503 reads (39%) | called by muse, mutect2, varscan2
- ARNTL2 | chr12:27421300 C>A | 3'Flank (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- ARPP21 | c.261+972G>T | Intron (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2
- BACH2 | c.*5296T>A | 3'UTR (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021586 G>A | 5'Flank (SNP) | VAF 58/113 reads (51%) | catalogued as COSV55848488; called by muse, mutect2, varscan2
- BET1 | c.-66C>T | 5'UTR (SNP) | VAF 36/390 reads (9%) | catalogued as rs890744351; called by muse, mutect2
- BTBD11 | c.1644-25G>A | Intron (SNP) | VAF 52/91 reads (57%) | catalogued as rs775867834; called by muse, mutect2, varscan2
- C5orf51 | c.*2900T>C | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- CBLN2 | c.*767A>T | 3'UTR (SNP) | VAF 4/29 reads (14%) | catalogued as rs1437369159; called by muse, mutect2, varscan2
- CDKN1B | c.-378G>A | 5'UTR (SNP) | VAF 84/173 reads (49%) | catalogued as rs978457845; called by muse, mutect2, varscan2
- CMC2 | c.81+362T>C | Intron (SNP) | VAF 22/22 reads (100%) | called by muse, mutect2, varscan2
- COL1A2 | c.*319T>C | 3'UTR (SNP) | VAF 4/71 reads (6%) | called by muse, mutect2
- COL27A1 | c.2368-1664C>T | Intron (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2, varscan2
- CRCT1 | c.*26C>A | 3'UTR (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- CSRNP1 | c.*402C>A | 3'UTR (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- CTBP2 | c.58+11513C>T | Intron (SNP) | VAF 32/472 reads (7%) | catalogued as rs765891634, COSV58340483; called by muse, mutect2
- CTBS | c.*784C>G | 3'UTR (SNP) | VAF 82/174 reads (47%) | catalogued as rs1225288287; called by muse, mutect2, varscan2
- CXCL3 | c.*201A>T | 3'UTR (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- DSC2 | c.*377del | 3'UTR (DEL) | VAF 19/178 reads (11%) | called by mutect2, pindel, varscan2
- FAM13C | c.1332+194C>A | Intron (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- FMN1 | c.*4879G>T | 3'UTR (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- FOXRED2 | c.*182G>A | 3'UTR (SNP) | VAF 25/231 reads (11%) | catalogued as rs770238548; called by muse, mutect2, varscan2
- GCSAML | c.*1113T>C | 3'UTR (SNP) | VAF 13/230 reads (6%) | called by muse, mutect2
- GLYATL1 | n.5G>A | RNA (SNP) | VAF 34/57 reads (60%) | called by muse, mutect2, varscan2
- H2BC5 | c.-15A>C | 5'UTR (SNP) | VAF 178/371 reads (48%) | catalogued as COSV99175303; called by muse, mutect2, varscan2
- HHIP | c.*6977C>A | 3'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- HIC2 | c.*2505G>C | 3'UTR (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.*1471A>G | 3'UTR (SNP) | VAF 56/133 reads (42%) | called by muse, mutect2, varscan2
- IGF2R | c.*107A>C | 3'UTR (SNP) | VAF 41/69 reads (59%) | called by muse, mutect2, varscan2
- INTU | c.1260-14T>A | Intron (SNP) | VAF 51/137 reads (37%) | called by muse, mutect2, varscan2
- JCAD | c.*2212C>T | 3'UTR (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- KCNAB2 | c.*514G>C | 3'UTR (SNP) | VAF 25/311 reads (8%) | called by muse, mutect2
- KMT2C | c.*971A>G | 3'UTR (SNP) | VAF 52/115 reads (45%) | called by muse, mutect2, varscan2
- LONRF2 | c.*5636A>C | 3'UTR (SNP) | VAF 94/184 reads (51%) | called by muse, mutect2
- LRRC37A5P | n.381C>T | RNA (SNP) | VAF 133/281 reads (47%) | called by muse, mutect2, varscan2
- LTB | c.162+133T>C | Intron (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851286 G>C | 5'Flank (SNP) | VAF 110/266 reads (41%) | catalogued as rs190042644; called by muse, varscan2
- NEBL | c.*1122A>T | 3'UTR (SNP) | VAF 93/165 reads (56%) | called by muse, mutect2, varscan2
- OR4C11 | c.*107C>A | 3'UTR (SNP) | VAF 38/79 reads (48%) | called by muse, mutect2, varscan2
- OTULIN | c.*2024T>A | 3'UTR (SNP) | VAF 10/141 reads (7%) | called by muse, mutect2
- PCNX2 | c.6241-266C>A | Intron (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2
- PDPR | c.2236-13C>A | Intron (SNP) | VAF 52/92 reads (57%) | catalogued as rs1183176070; called by muse, mutect2, varscan2
- PEF1 | c.*216A>G | 3'UTR (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- PEG3 | c.*2574A>T | 3'UTR (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- PEG3 | c.*2383T>A | 3'UTR (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- PLXNC1 | c.3598-1651T>C | Intron (SNP) | VAF 53/513 reads (10%) | called by muse, mutect2, varscan2
- POSTN | c.*53C>T | 3'UTR (SNP) | VAF 73/164 reads (45%) | catalogued as rs1052211146; called by muse, mutect2, varscan2
- PPM1A | c.952+846T>G | Intron (SNP) | VAF 5/103 reads (5%) | called by muse, mutect2
- PRMT8 | c.418-767G>A | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as rs754314980; called by mutect2, varscan2
- RASEF | c.*1147C>A | 3'UTR (SNP) | VAF 61/131 reads (47%) | called by muse, mutect2, varscan2
- RIMBP2 | c.*2179T>C | 3'UTR (SNP) | VAF 11/202 reads (5%) | called by muse, mutect2
- RPL14P1 | n.580G>A | RNA (SNP) | VAF 56/293 reads (19%) | called by muse, mutect2, varscan2
- RPS6KB2 | c.120-35G>A | Intron (SNP) | VAF 8/241 reads (3%) | called by muse, mutect2
- S1PR3 | c.-148+1625A>T | Intron (SNP) | VAF 27/120 reads (23%) | called by muse, mutect2, varscan2
- SEC16B | c.999-52C>G | Intron (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- SERPINA3 | c.-8-806G>T | Intron (SNP) | VAF 36/259 reads (14%) | called by muse, mutect2, varscan2
- SLC37A2 | c.*506T>C | 3'UTR (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- SMOC1 | c.584-92T>G | Intron (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- SPATA13 | c.*452T>G | 3'UTR (SNP) | VAF 47/432 reads (11%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20316771 C>T | 3'Flank (SNP) | VAF 60/107 reads (56%) | called by muse, mutect2, varscan2
- SULT1B1 | c.*76T>A | 3'UTR (SNP) | VAF 28/113 reads (25%) | called by muse, mutect2, varscan2
- TAFA1 | c.*1087C>A | 3'UTR (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- TFF2 | c.*14C>G | 3'UTR (SNP) | VAF 111/510 reads (22%) | called by muse, mutect2, varscan2
- TFF2 | c.*13C>A | 3'UTR (SNP) | VAF 110/504 reads (22%) | called by muse, mutect2, varscan2
- TMEM163 | c.*587G>A | 3'UTR (SNP) | VAF 61/132 reads (46%) | catalogued as rs371242549; called by muse, mutect2, varscan2
- TRIM33 | c.*4558C>A | 3'UTR (SNP) | VAF 28/176 reads (16%) | called by muse, mutect2, varscan2
- USP20 | c.-10C>T | 5'UTR (SNP) | VAF 82/301 reads (27%) | called by muse, mutect2, varscan2
- USP20 | c.*100C>A | 3'UTR (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- WWC3 | c.*2336T>G | 3'UTR (SNP) | VAF 53/345 reads (15%) | called by muse, mutect2, varscan2
- XCL1 | c.*508A>C | 3'UTR (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- ZFP91 | c.*908G>A | 3'UTR (SNP) | VAF 22/302 reads (7%) | called by muse, mutect2
- ZNF138 | c.*676C>G | 3'UTR (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2
- ZNF189 | c.*214_*217del | 3'UTR (DEL) | VAF 8/38 reads (21%) | catalogued as rs1242804910; called by mutect2, pindel, varscan2
- ZNF807P | n.1236G>A | RNA (SNP) | VAF 76/177 reads (43%) | called by muse, mutect2, varscan2
